Somatic mutation profile of tumor specimen TCGA-EA-A3QE-01A (aliquot TCGA-EA-A3QE-01A-21D-A21Q-09) from TCGA case TCGA-EA-A3QE, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 45.1 years (16,460 days).
Specimen TCGA-EA-A3QE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ce5d34f-6f9a-402c-9fa7-8a6c8a3bf249.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A3QE-10A (Blood Derived Normal), aliquot TCGA-EA-A3QE-10A-01D-A21Q-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66f46475-762f-402d-8279-67b4df41510b

The open-access MAF lists 70 somatic variants for this specimen: 53 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 15, Nonsense Mutation 7, 5'UTR 1, Splice Region 1, Frame Shift Del 1, Intron 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCD3 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV64644351; called by muse, mutect2, varscan2
- ADGRA3 | c.1324C>T p.R442* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as COSV51568135; called by muse, mutect2, varscan2
- ADGRB2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV57078616; called by muse, mutect2, varscan2
- ADGRG6 | c.809G>C p.R270T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.186); catalogued as rs1338047770, COSV51600680, COSV99747549; called by muse, mutect2, varscan2
- ADH7 | c.448C>A p.H150N | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV52923148; called by muse, mutect2, varscan2
- ALDH1L1 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV56419092; called by muse, mutect2, varscan2
- ARHGAP36 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52271626; called by muse, mutect2, varscan2
- ARL14EP | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56343585; called by muse, mutect2, varscan2
- ATF7IP | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); catalogued as COSV53777306; called by muse, mutect2
- CD109 | c.3265C>G p.L1089V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV54649548, COSV54656637, COSV99753902; called by muse, mutect2, varscan2
- CENPI | c.1829A>G p.Y610C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54506135; called by muse, mutect2, varscan2
- CNTNAP2 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV62253090; called by muse, mutect2, varscan2
- CNTNAP3 | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.02); catalogued as COSV52675338, COSV99905778; called by muse, mutect2, varscan2
- COBLL1 | c.514G>A p.D172N (on ENST00000392717; = p.D134N on NM_014900.5) | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as rs868142959, COSV52076048; called by muse, mutect2, varscan2
- CTNNA2 | c.1415G>A p.R472Q | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.149); catalogued as rs1224021331, COSV58179198; called by muse, mutect2, varscan2
- DCC | c.2269G>A p.G757S | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59133918; called by muse, mutect2, varscan2
- DENND2B | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.024); catalogued as COSV58207689; called by muse, mutect2, varscan2
- DNAH11 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.604); catalogued as COSV100180329; called by muse, mutect2
- EGFL6 | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as rs777299988, COSV63635254; called by muse, mutect2, varscan2
- F8 | c.6355C>T p.Q2119* | Nonsense Mutation (SNP) | VAF 5/98 reads (5%) | catalogued as CM123920, CM1314197, COSV100811792; called by muse, mutect2
- FCGR2A | c.717C>G p.I239M (on ENST00000271450 / NM_001136219.3; = p.I238M on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/265 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.809); catalogued as COSV99615646; called by muse, mutect2
- FLNA | c.4772C>T p.P1591L | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs372729831, COSV61051083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSTZ1 | c.607C>T p.H203Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV53624565; called by muse, mutect2, varscan2
- INAVA | c.777G>A p.E259= | Splice Region (SNP) | VAF 27/103 reads (26%) | catalogued as rs1232770908, COSV66257476; called by muse, mutect2, varscan2
- INPP4B | c.364C>A p.H122N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV53717923, COSV99526174; called by muse, mutect2, varscan2
- LETM1 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as rs867332327, COSV57104334; called by muse, mutect2, varscan2
- MAPKAPK5 | c.1300G>C p.D434H (on ENST00000551404 / NM_139078.3; = p.D432H on NM_003668.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.264); catalogued as COSV101612324, COSV73436143; called by muse, mutect2, varscan2
- MPO | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.178); catalogued as rs752277567, COSV56561295, COSV99832376; called by muse, mutect2, varscan2
- MTFR2 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as rs141467777; called by muse, mutect2, varscan2
- MYH11 | c.769G>A p.V257M | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.857); catalogued as rs112992497, COSV55557421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFYB | c.550C>G p.Q184E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.074); catalogued as COSV53530516; called by muse, mutect2, varscan2
- NLRP12 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs781218927, COSV60754994; called by muse, mutect2
- NOTCH1 | c.4952C>T p.S1651L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs1243453790, COSV53089562; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRG3 | c.433G>A p.A145T | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV64583193; called by muse, mutect2, varscan2
- NTRK3 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as COSV58142046; called by muse, mutect2, varscan2
- OR4C3 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV60590266; called by muse, mutect2
- PCSK6 | c.2548C>T p.H850Y | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as COSV61860387; called by muse, mutect2
- PTPN4 | c.1397C>G p.P466R | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV55308886; called by muse, mutect2
- ROS1 | c.1726C>T p.Q576* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV63861456; called by muse, mutect2
- SEC14L1 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.652); catalogued as rs752687715, COSV66725277; called by muse, mutect2, varscan2
- SERPINC1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs201541724, COSV62930581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNAP23 | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV51041573, COSV51042221; called by muse, mutect2, varscan2
- TEX35 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs771118926, COSV51108427; called by muse, mutect2
- TRIM7 | c.855C>A p.F285L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV51250811; called by muse, mutect2, varscan2
- TTI1 | c.317C>T p.S106L | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV65063416; called by muse, mutect2
- UBXN2B | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1414923019, COSV68309715; called by muse, mutect2
- WDR91 | c.1145C>T p.S382L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs750778049, COSV60371821; called by muse, mutect2, varscan2
- ZNF746 | c.1789C>T p.R597* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as rs756247448, COSV61408785; called by muse, mutect2, varscan2
- HCFC1 | c.881_883dup p.N294dup | In Frame Ins (INS) | VAF 24/131 reads (18%) | called by mutect2, pindel, varscan2
- HLA-A | c.95_98del p.F32Sfs*44 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- SLC25A36 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- ABCB8 | c.1125C>T p.I375= (on ENST00000297504 / NM_001282291.2; = p.I358= on NM_007188.5) | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs148169229; called by muse, mutect2, varscan2
- C19orf47 | c.1161G>A p.R387= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV63511060; called by muse, mutect2, varscan2
- CD226 | c.402G>T p.V134= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV54616023; called by muse, mutect2, varscan2
- ERBB2 | c.3726G>A p.T1242= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs753222413, COSV54082464; called by muse, mutect2, varscan2
- GAS2L3 | c.105C>T p.Y35= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as rs776903194, COSV57159031; called by mutect2, varscan2
- GP6 | c.186G>A p.L62= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV59979585; called by muse, mutect2, varscan2
- ITGB6 | c.1087C>T p.L363= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV51798471; called by muse, mutect2, varscan2
- KIAA1614 | c.3183G>A p.R1061= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV62551775; called by muse, mutect2, varscan2
- KIF19 | c.2646G>A p.E882= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100739157; called by muse, mutect2
- PAK5 | c.1917C>T p.G639= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs191751301, COSV62037817; called by muse, mutect2, varscan2
- PCDHGA2 | c.1674C>T p.N558= | Silent (SNP) | VAF 22/97 reads (23%) | catalogued as rs150000282; called by muse, mutect2, varscan2
- RTL8C | c.45G>A p.P15= | Silent (SNP) | VAF 26/75 reads (35%) | catalogued as COSV57060670; called by muse, mutect2, varscan2
- TAS1R1 | c.1662G>A p.P554= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs776544185, COSV59840748; called by muse, mutect2, varscan2
- TENM2 | c.2040C>T p.H680= (on ENST00000518659 / NM_001122679.2; = p.H448= on NM_001080428.3) | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as rs369986376, COSV69144506; called by muse, mutect2, varscan2
- UBE3C | c.2898T>C p.G966= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV61955538; called by mutect2, varscan2
- PHACTR4 | c.-116G>A | 5'UTR (SNP) | VAF 14/81 reads (17%) | catalogued as rs1377716102, COSV65787635; called by muse, mutect2, varscan2
- RGS3 | c.897+3508C>A | Intron (SNP) | VAF 19/84 reads (23%) | catalogued as COSV58285377; called by muse, mutect2, varscan2
